Somatic mutation profile of tumor specimen TCGA-19-2629-01A (aliquot TCGA-19-2629-01A-01W-0922-08) from TCGA case TCGA-19-2629, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.9 years (22,257 days).
Specimen TCGA-19-2629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 729f922b-f6b0-4e70-aa48-e24e02095002.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2629-10A (Blood Derived Normal), aliquot TCGA-19-2629-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d94721a7-f052-4faa-9011-df22db6e9996

The open-access MAF lists 92 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Del 13, In Frame Del 7, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1382_1384del p.R461_E462delinsQ (on ENST00000521381 / NM_181523.3; = p.R191_E192delinsQ on NM_181504.4) | In Frame Del (DEL) | VAF 4/14 reads (29%) | hotspot (GDC flag); catalogued as COSV57135274; called by mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 53/91 reads (58%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABL2 | c.2465C>A p.P822Q (on ENST00000502732 / NM_007314.4; = p.P807Q on NM_005158.5) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV61021366; called by muse, mutect2
- AKAP11 | c.5002A>G p.S1668G | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV50295843; called by muse, mutect2, varscan2
- ARHGAP32 | c.4241C>G p.P1414R (on ENST00000310343 / NM_001378025.1; = p.P1065R on NM_014715.4) | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59846407; called by muse, mutect2, varscan2
- CERS6 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372014490; called by muse, mutect2
- CFTR | c.1079C>G p.T360R | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs75053309, CM983548, COSV50048586; called by muse, mutect2, varscan2
- CP | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52830187; called by muse, mutect2
- CYP2E1 | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV53313109, COSV99428836; called by muse, mutect2, varscan2
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 113/327 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2, varscan2
- DNAJB4 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.074); catalogued as COSV66131521; called by muse, mutect2, varscan2
- DPYSL5 | c.1438_1440del p.K480del | In Frame Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs772460158; called by mutect2, pindel, varscan2
- EVA1A | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 184/500 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs761321988, COSV52057958; called by muse, mutect2, varscan2
- FAM234B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750265649, COSV52194244; called by muse, mutect2, varscan2
- FAT2 | c.3695T>C p.I1232T | Missense Mutation (SNP) | VAF 147/399 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1485991417, COSV55818194; called by muse, mutect2, varscan2
- FER1L6 | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1471830435, COSV67549473; called by muse, mutect2, varscan2
- FGFR4 | c.1220A>C p.Q407P | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV52802718; called by muse, mutect2, varscan2
- FXN | c.325G>T p.E109* (on ENST00000377270; = p.E184* on NM_000144.5) | Nonsense Mutation (SNP) | VAF 35/248 reads (14%) | catalogued as COSV66009706; called by muse, mutect2, varscan2
- H3C7 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV55099706; called by muse, mutect2
- JMJD1C | c.5230_5232del p.E1744del | In Frame Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1378403076; called by pindel, varscan2
- KCNE1 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV61606563; called by muse, mutect2, varscan2
- KIAA0319 | c.2570T>C p.I857T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV65497819; called by muse, mutect2, varscan2
- KIDINS220 | c.4160A>G p.Y1387C | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56752530; called by muse, mutect2, varscan2
- LGI2 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1158549773, COSV66122823; called by muse, mutect2, varscan2
- MCHR1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs199697488, COSV50760980; called by muse, mutect2, varscan2
- MFAP3L | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV64372093; called by muse, mutect2, varscan2
- MT1A | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs917775878, COSV51947321; called by mutect2, varscan2
- MYH4 | c.4993A>T p.I1665F | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55116753; called by muse, mutect2, varscan2
- MYH7B | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1190716212, COSV53418992; called by muse, mutect2, varscan2
- NDUFS2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 33/204 reads (16%) | catalogued as rs534026057, COSV57154544; called by muse, mutect2, varscan2
- NEB | c.5921A>G p.D1974G | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51131689; called by muse, mutect2, varscan2
- NEPRO | c.1537A>G p.M513V | Missense Mutation (SNP) | VAF 215/592 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs774892630, COSV55606398; called by muse, mutect2, varscan2
- NEURL4 | c.3130dup p.A1044Gfs*3 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs754613626; called by pindel, varscan2
- NICN1 | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV56469404; called by muse, mutect2, varscan2
- OR6K2 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 299/650 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1376170463, COSV62743389; called by muse, mutect2, varscan2
- PCDH18 | c.2787C>A p.D929E | Missense Mutation (SNP) | VAF 96/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100787264, COSV61267815; called by muse, mutect2, varscan2
- PKHD1L1 | c.5882A>G p.N1961S | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV65741649; called by muse, mutect2
- PTPRT | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776134993, COSV61967335, COSV62035210; called by muse, mutect2, varscan2
- RAB23 | c.664_667del p.Q222Gfs*24 | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | catalogued as rs764844543; called by pindel, varscan2
- RNASE4 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 100/539 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs756611890, COSV59011978, COSV59012680; called by muse, mutect2, varscan2
- SEPTIN10 | c.59C>G p.T20R | Missense Mutation (SNP) | VAF 50/618 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as COSV61780023; called by muse, mutect2
- SETBP1 | c.3785G>C p.R1262T | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV56315003, COSV56319673; called by muse, mutect2, varscan2
- SPACA1 | c.520A>C p.K174Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1223017322, COSV52759622; called by muse, mutect2
- SPOCK3 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV62723736; called by muse, mutect2, varscan2
- SSR2 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 99/209 reads (47%) | catalogued as COSV55303699; called by muse, mutect2, varscan2
- SYT13 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753970325, COSV50073275; called by muse, mutect2, varscan2
- TDRD7 | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 318/887 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV62429163, COSV62429170; called by muse, mutect2, varscan2
- TENM4 | c.3250A>G p.I1084V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.891); catalogued as rs1286642519, COSV53623161; called by muse, mutect2, varscan2
- TMED5 | c.661_664del p.F221Kfs*13 | Frame Shift Del (DEL) | VAF 43/121 reads (36%) | catalogued as rs1473965497; called by mutect2, pindel, varscan2
- TMEM214 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53192276; called by muse, mutect2, varscan2
- TULP1 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV57692451; called by muse, mutect2, varscan2
- UGT2A3 | c.996+2T>C p.X332_splice | Splice Site (SNP) | VAF 47/663 reads (7%) | catalogued as COSV52359732; called by muse, mutect2
- USP29 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs1568456221, COSV54141953; called by muse, mutect2, varscan2
- VEPH1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 125/999 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62878221; called by muse, mutect2, varscan2
- ARID2 | c.4017_4018del p.N1340Lfs*12 | Frame Shift Del (DEL) | VAF 71/222 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.1073_1074del p.K358Tfs*3 | Frame Shift Del (DEL) | VAF 72/110 reads (65%) | called by pindel, varscan2
- CENPU | c.256_258del p.E86del | In Frame Del (DEL) | VAF 13/121 reads (11%) | called by pindel, varscan2
- CNOT1 | c.6447_6451del p.N2149Kfs*7 | Frame Shift Del (DEL) | VAF 127/399 reads (32%) | called by mutect2, pindel, varscan2
- DDX17 | c.1282_1283del p.K428Efs*4 | Frame Shift Del (DEL) | VAF 58/326 reads (18%) | called by mutect2, pindel, varscan2
- DGAT1 | c.1230del p.S411Rfs*9 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel*
- GMPR2 | c.829_831del p.K277del (on ENST00000355299 / NM_001351022.2; = p.K295del on NM_016576.5) | In Frame Del (DEL) | VAF 40/134 reads (30%) | called by pindel, varscan2
- HOMER1 | c.66_68del p.K22del | In Frame Del (DEL) | VAF 197/504 reads (39%) | called by pindel, varscan2
- HSDL2 | c.555del p.E185Dfs*65 | Frame Shift Del (DEL) | VAF 143/471 reads (30%) | called by mutect2, pindel, varscan2
- MYO18A | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYO5B | c.1708_1709del p.D570Hfs*4 | Frame Shift Del (DEL) | VAF 150/644 reads (23%) | called by pindel, varscan2
- PSMC3 | c.375_376del p.K125Nfs*18 | Frame Shift Del (DEL) | VAF 72/200 reads (36%) | called by mutect2, pindel, varscan2
- SMURF1 | c.1678_1680del p.N560del | In Frame Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel, varscan2
- SPEF2 | c.3900dup p.V1301Sfs*18 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by pindel, varscan2
- TMIGD2 | c.347_348del p.V116Gfs*4 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.410del p.G137Dfs*19 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | called by mutect2, pindel, varscan2
- USP53 | c.2543_2544del p.S848Cfs*9 | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | called by pindel, varscan2
- VWF | c.7525dup p.D2509Gfs*24 | Frame Shift Ins (INS) | VAF 35/275 reads (13%) | called by mutect2, pindel, varscan2
- CFAP100 | c.801G>A p.S267= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs757315451, COSV61502891; called by muse, mutect2, varscan2
- FAM83G | c.397C>T p.L133= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs763540091, COSV58757414; called by muse, mutect2
- FREM2 | c.6786A>G p.E2262= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV54835207; called by muse, mutect2, varscan2
- H4-16 | c.258T>C p.D86= | Silent (SNP) | VAF 33/409 reads (8%) | catalogued as rs759672780, COSV63762044; called by muse, mutect2
- ITPRID1 | c.825G>A p.E275= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as COSV60073208; called by muse, mutect2, varscan2
- KCTD9 | c.1149C>T p.H383= | Silent (SNP) | VAF 51/444 reads (11%) | catalogued as COSV55339914; called by muse, mutect2
- KRTAP10-2 | c.159G>C p.V53= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs587703858, COSV59959248; called by muse, varscan2
- MYH1 | c.5685C>A p.V1895= | Silent (SNP) | VAF 282/893 reads (32%) | catalogued as COSV56846965, COSV56856675; called by muse, mutect2, varscan2
- NCALD | c.447A>G p.T149= | Silent (SNP) | VAF 109/288 reads (38%) | catalogued as COSV55272126; called by muse, mutect2, varscan2
- NCOA2 | c.1323T>C p.F441= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV71763846; called by muse, mutect2, varscan2
- NUP210 | c.501G>A p.A167= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1344211903, COSV54405410; called by muse, mutect2, varscan2
- ODF2L | c.1422G>A p.A474= (on ENST00000317336; = p.A445= on NM_020729.3) | Silent (SNP) | VAF 93/206 reads (45%) | catalogued as rs372029682; called by muse, mutect2, varscan2
- OSBP2 | c.699G>A p.A233= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as rs1249967056, COSV60241873; called by muse, mutect2
- POLR3D | c.513C>T p.N171= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as rs1207239892, COSV60570992; called by muse, mutect2, varscan2
- SGSH | c.927C>T p.S309= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1385473515, COSV58339086; called by muse, mutect2, varscan2
- SLC12A3 | c.360C>T p.G120= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs753383791, COSV52634275; called by muse, mutect2
- ZNF142 | c.48G>A p.E16= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV63719709; called by muse, mutect2, varscan2
- ANKRD20A4P | c.*1A>G | 3'UTR (SNP) | VAF 10/72 reads (14%) | catalogued as rs750366282, COSV100628549; called by muse, mutect2, varscan2
- IGHV1-12 | n.135A>G | RNA (SNP) | VAF 83/277 reads (30%) | catalogued as rs370639070; called by muse, mutect2, varscan2
